Gene-level copy-number profile of tumor specimen TCGA-AG-3881-01A from TCGA case TCGA-AG-3881, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IIA; Age at diagnosis: 83.4 years (30,467 days).
Specimen TCGA-AG-3881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.9d6ed684-fa84-474c-b54c-58ffbcf44bc8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3881-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47703aa7-9862-4075-8476-6b9e57268735

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 1,272; copy number 2: 28,384; copy number 3: 21,571; copy number 4: 7,010; copy number 5: 186; copy number 6: 136; copy number 7: 34; copy number 8: 1,023; copy number 9: 53; copy number 10: 24; copy number 14: 1; copy number 17: 29; copy number 18: 4; copy number 21: 10; copy number 26: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3881-01A-01D-0903-01): tumor purity 0.67, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:15,928,296–16,645,467, 1 gene (within-gene range 0–2): MIR99AHG.
- chr21:16,094,415–16,873,691, 14 genes: VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,567 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–70,414,624, 987 genes, copy number 7–8 (broad region; genes not listed).
- chr10:74,151,202–80,941,201, 142 genes, copy number 8–26 (within-gene range 3–26) (broad region; genes not listed).
- chr12:674,801–6,961,316, 185 genes, copy number 6–21 (within-gene range 4–21) (broad region; genes not listed).
- chr12:16,188,485–21,541,249, 67 genes, copy number 6–10 (broad region; genes not listed).
- chr12:22,609,228–30,307,611, 127 genes, copy number 5 (broad region; genes not listed).
- chr12:30,861,921–31,015,806, 4 genes, copy number 5: PPIAP44, TSPAN11, AC008013.1, AC008013.2.
- chr12:31,280,422–32,755,897, 55 genes, copy number 5: AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4.

Autosomal genes at a single copy (total copy number 1): 1,272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
